Somatic mutation profile of tumor specimen C3L-06338-03 (aliquot CPT0363410009) from CPTAC case C3L-06338, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 59.3 years (21,650 days).
Specimen C3L-06338-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2f5af4a-9778-4cb9-95fa-5bcb9be590fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06338-31 (Blood Derived Normal), aliquot CPT0363450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eec926c2-c188-44bd-9d5a-e0ff07cd4846

The open-access MAF lists 321 somatic variants for this specimen: 207 protein-altering or splice-affecting, 102 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 182, Silent 102, Nonsense Mutation 13, Splice Region 8, Intron 5, 3'Flank 3, Frame Shift Del 2, 3'UTR 2, In Frame Del 1, In Frame Ins 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 577/976 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PKHD1 | c.11695C>T p.Q3899* | Nonsense Mutation (SNP) | VAF 30/1182 reads (3%) | catalogued as rs1295732689; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.636del p.R213Dfs*34 | Frame Shift Del (DEL) | VAF 543/925 reads (59%) | catalogued as rs864309495, CD011205, COSV52729299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.1260G>A p.K420= | Splice Region (SNP) | VAF 414/755 reads (55%) | catalogued as COSV101330177; called by muse, mutect2, varscan2
- ADCY8 | c.3682C>T p.R1228W | Missense Mutation (SNP) | VAF 349/934 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs981604557, COSV53905043; called by muse, varscan2
- ALB | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 483/629 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV55736272; called by muse, mutect2, varscan2
- APC | c.6194C>T p.P2065L | Missense Mutation (SNP) | VAF 502/688 reads (73%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs112487226, COSV57330881; called by muse, varscan2
- ARHGAP29 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 358/1327 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV53117108; called by muse, mutect2, varscan2
- BCL11B | c.1885G>T p.G629C (on ENST00000357195 / NM_001282237.2; = p.G558C on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 232/509 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs1326410828; called by muse, mutect2, varscan2
- BMPR2 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 512/649 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65814001; called by muse, varscan2
- CABIN1 | c.4648C>T p.R1550C | Missense Mutation (SNP) | VAF 250/988 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs149769745; called by muse, varscan2
- CACNA1A | c.3884T>C p.M1295T | Missense Mutation (SNP) | VAF 286/761 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64201396; called by muse, mutect2, varscan2
- CHRM5 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 456/665 reads (69%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV67248667; called by muse, mutect2, varscan2
- CNTNAP2 | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 444/784 reads (57%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as rs1481558419; called by muse, mutect2, varscan2
- COL12A1 | c.4795C>T p.R1599* | Nonsense Mutation (SNP) | VAF 546/723 reads (76%) | catalogued as COSV100485159, COSV59401096; called by muse, varscan2
- COL18A1 | c.3232G>A p.G1078R (on ENST00000359759 / NM_130444.3; = p.G843R on NM_030582.4) | Missense Mutation (SNP) | VAF 790/1059 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs550223927, COSV60589420; called by muse, mutect2, varscan2
- COL5A1 | c.161G>C p.G54A | Missense Mutation (SNP) | VAF 335/769 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1393560967, COSV65673650; called by muse, mutect2, varscan2
- COL6A5 | c.3396C>A p.D1132E | Missense Mutation (SNP) | VAF 322/1233 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as rs1428867836; called by muse, mutect2, varscan2
- COL6A5 | c.3397C>T p.L1133F | Missense Mutation (SNP) | VAF 321/1230 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.412); catalogued as COSV55214380; called by muse, mutect2, varscan2
- CPA5 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 272/1155 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs782787226, COSV100812506; called by muse, mutect2, varscan2
- CPED1 | c.1042G>A p.G348R | Missense Mutation (SNP) | VAF 184/937 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774754179; called by muse, mutect2, varscan2
- CROCC | c.2948C>T p.S983F | Missense Mutation (SNP) | VAF 566/1078 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs1231600904, COSV65011410; called by mutect2, varscan2
- CSMD3 | c.7864G>T p.A2622S (on ENST00000297405 / NM_001363185.1; = p.A2518S on NM_052900.3) | Missense Mutation (SNP) | VAF 294/788 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.019); catalogued as COSV99836906; called by muse, varscan2
- CTSB | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 278/440 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.173); catalogued as rs147604039; called by muse, mutect2, varscan2
- CYP17A1 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 570/861 reads (66%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.633); catalogued as rs1393268729; called by muse, mutect2, varscan2
- DAGLA | c.3119C>G p.S1040* | Nonsense Mutation (SNP) | VAF 394/519 reads (76%) | catalogued as rs371510242; called by muse, varscan2
- DCX | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 416/545 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as rs727503897, COSV100576494, COSV57567054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH10 | c.5003G>A p.G1668D (on ENST00000409039; = p.G1607D on NM_207437.3) | Missense Mutation (SNP) | VAF 377/1566 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV101292207; called by muse, mutect2, varscan2
- DYNC2H1 | c.12577C>T p.R4193C | Missense Mutation (SNP) | VAF 246/398 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369231694; called by muse, varscan2
- ENO4 | c.1634G>A p.R545Q (on ENST00000622726; = p.R542Q on NM_001242699.2) | Missense Mutation (SNP) | VAF 354/729 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.089); catalogued as rs1404776625; called by muse, mutect2, varscan2
- EPHA6 | c.583T>C p.Y195H | Missense Mutation (SNP) | VAF 816/1460 reads (56%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.929); catalogued as COSV67566623; called by muse, mutect2, varscan2
- FAM83A | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 522/1349 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs1190164701; called by muse, mutect2, varscan2
- FAT4 | c.13615C>T p.P4539S | Missense Mutation (SNP) | VAF 815/1094 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs759702540, COSV58700327; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 269/939 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); catalogued as COSV100436848; called by muse, mutect2, varscan2
- HHLA2 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 484/1670 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV63318315; called by muse, mutect2, varscan2
- HSP90B1 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 249/680 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as rs200307600; called by muse, mutect2, varscan2
- HYDIN | c.11689G>A p.G3897R | Missense Mutation (SNP) | VAF 398/632 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66638493; called by muse, mutect2, varscan2
- HYDIN | c.6607G>A p.G2203R | Missense Mutation (SNP) | VAF 532/847 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762961047, COSV59272155; called by muse, mutect2, varscan2
- IGHM | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 798/1023 reads (78%) | SIFT tolerated (0.78); catalogued as rs368571679; called by muse, varscan2
- IL1RAPL2 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 432/577 reads (75%) | SIFT tolerated (0.41); PolyPhen benign (0.248); catalogued as rs1298370119, COSV61158149; called by muse, mutect2, varscan2
- KDM7A | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 158/812 reads (19%) | catalogued as COSV50092260, COSV50094257; called by muse, mutect2, varscan2
- KIAA0232 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 568/805 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV56927562, COSV56930503; called by mutect2, varscan2
- KRT39 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 589/787 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs753269338; called by muse, mutect2, varscan2
- KRT6A | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 251/1053 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV58103622; called by muse, mutect2, varscan2
- L3MBTL1 | c.1201G>A p.E401K (on ENST00000418998 / NM_001377303.1; = p.E311K on NM_015478.7) | Missense Mutation (SNP) | VAF 298/488 reads (61%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.824); catalogued as COSV64228887; called by muse, mutect2, varscan2
- LRP2BP | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 565/745 reads (76%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs765318312, COSV60749954; called by muse, mutect2, varscan2
- LYPD2 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 238/700 reads (34%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.911); catalogued as rs909927201; called by muse, mutect2, varscan2
- MAGEB18 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 512/647 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs773051777; called by muse, mutect2, varscan2
- MORC1 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 201/672 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV51732543; called by muse, mutect2, varscan2
- MUC4 | c.4564C>T p.P1522S | Missense Mutation (SNP) | VAF 213/1468 reads (15%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.65); catalogued as rs1165300856; called by muse, mutect2, varscan2
- MYH11 | c.4171G>A p.E1391K | Missense Mutation (SNP) | VAF 596/797 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs748813945, COSV55552583; called by muse, mutect2, varscan2
- MYLPF | c.128G>A p.G43D | Missense Mutation (SNP) | VAF 729/904 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58443978; called by muse, mutect2, varscan2
- MYO1H | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 770/1422 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.355); catalogued as rs1272052176; called by muse, varscan2
- NCKAP5L | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 466/1240 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); catalogued as COSV100258718; called by muse, mutect2, varscan2
- NGF | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 766/1338 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs1011323001, COSV101049438; ClinVar: uncertain significance; called by muse, varscan2
- NIBAN3 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 478/1219 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV56308910; called by muse, mutect2, varscan2
- NPAS1 | c.525G>A p.V175= | Splice Region (SNP) | VAF 342/823 reads (42%) | catalogued as rs767993138, COSV71384006; called by muse, mutect2, varscan2
- NWD1 | c.2038G>A p.V680I | Missense Mutation (SNP) | VAF 344/1028 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs575310279, COSV60346465; called by muse, varscan2
- ODAPH | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 400/539 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.324); catalogued as COSV100290318, COSV61141011; called by muse, varscan2
- OR3A1 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 670/841 reads (80%) | SIFT tolerated (0.13); PolyPhen benign (0.292); catalogued as rs540886927, COSV60163122; called by muse, varscan2
- OR51B5 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 417/571 reads (73%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs752700199; called by muse, mutect2, varscan2
- OR6C1 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 271/786 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as COSV101110514; called by muse, varscan2
- PCDHGA7 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 596/835 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99548603; called by muse, varscan2
- PCOLCE2 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 281/939 reads (30%) | catalogued as COSV99930368; called by muse, mutect2, varscan2
- PGK2 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 743/1430 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs773748885, COSV59163097; called by muse, varscan2
- PHF23 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 924/1206 reads (77%) | catalogued as COSV50038421; called by muse, mutect2, varscan2
- PIK3CG | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 801/1356 reads (59%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs1293906030, COSV63251069; called by muse, mutect2, varscan2
- PIWIL2 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 268/436 reads (61%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.09); catalogued as rs202094774, COSV63249870; called by muse, varscan2
- PLCL1 | c.2997G>A p.G999= | Splice Region (SNP) | VAF 116/656 reads (18%) | catalogued as rs1214851737; called by muse, mutect2, varscan2
- PLEKHA7 | c.2017C>T p.R673W | Missense Mutation (SNP) | VAF 445/631 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs760552278; called by muse, mutect2, varscan2
- PRR12 | c.2231C>T p.A744V (on ENST00000615927; = p.A1565V on NM_020719.3) | Missense Mutation (SNP) | VAF 499/1318 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.161); catalogued as COSV69816720; called by muse, mutect2, varscan2
- RESF1 | c.1513C>T p.P505S | Missense Mutation (SNP) | VAF 415/822 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as COSV100440694; called by muse, varscan2
- RFX6 | c.1822G>A p.G608R | Missense Mutation (SNP) | VAF 433/647 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV60586261; called by muse, mutect2, varscan2
- RSPO1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 717/1428 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs778964874; called by muse, varscan2
- SAMD9L | c.3196G>A p.D1066N | Missense Mutation (SNP) | VAF 641/1122 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.08); catalogued as rs1365483356; called by muse, mutect2, varscan2
- SCN1B | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 374/916 reads (41%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.482); catalogued as COSV52894505; called by muse, mutect2, varscan2
- SDK1 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 732/1330 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs371081530; called by muse, varscan2
- SDR16C5 | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 325/842 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as COSV58126151; called by muse, mutect2, varscan2
- SERINC4 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 426/651 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs1471048346; called by muse, mutect2, varscan2
- SLC6A9 | c.1741C>T p.P581S (on ENST00000360584 / NM_201649.4; = p.P527S on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 554/988 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772864075; called by muse, mutect2, varscan2
- SNAPC3 | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 266/469 reads (57%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs769563858; called by muse, mutect2, varscan2
- SPAM1 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 539/922 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56141239; called by muse, mutect2, varscan2
- SPATA31E1 | c.2602C>T p.P868S | Missense Mutation (SNP) | VAF 331/1172 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs201720387; called by muse, mutect2, varscan2
- SPATA31E1 | c.4015C>T p.P1339S | Missense Mutation (SNP) | VAF 485/1069 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.099); catalogued as rs1309889642, COSV57789505, COSV57792800; called by muse, mutect2, varscan2
- SPSB3 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 574/811 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769336234; called by muse, varscan2
- ST18 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 307/833 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV52504305; called by muse, mutect2, varscan2
- TACR3 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 474/669 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1383571483, COSV59200138, COSV59209171; called by muse, mutect2, varscan2
- TENM4 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 486/770 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs758451846, COSV53624676; called by muse, mutect2, varscan2
- TEX101 | c.253G>A p.G85R (on ENST00000598265 / NM_001130011.3; = p.G103R on NM_031451.4) | Missense Mutation (SNP) | VAF 370/903 reads (41%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.843); catalogued as rs761316843, COSV53661503; called by muse, mutect2, varscan2
- TJP3 | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 355/1024 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs776872951; called by muse, mutect2
- TPTE2 | c.376C>T p.R126* (on ENST00000400230 / NM_199254.2; = p.R89* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 252/377 reads (67%) | catalogued as rs770030606, COSV55016302; called by muse, mutect2, varscan2
- TRAV36DV7 | c.51C>T p.S17= | Splice Region (SNP) | VAF 746/854 reads (87%) | catalogued as rs770501462; called by muse, mutect2, varscan2
- TRPM2 | c.4166G>A p.G1389E | Missense Mutation (SNP) | VAF 377/519 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1168512407; called by muse, mutect2, varscan2
- TTLL10 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 773/1487 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1020191830; called by muse, mutect2, varscan2
- TTN | c.39667G>A p.V13223I (on ENST00000591111; = p.V5799I on NM_003319.4) | Missense Mutation (SNP) | VAF 795/971 reads (82%) | PolyPhen benign (0.343); catalogued as rs535221404; called by muse, mutect2, varscan2
- UNC13C | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 402/621 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); catalogued as COSV52880645; called by muse, mutect2, varscan2
- UNC93A | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 254/414 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as rs1393273761, COSV57810852; called by muse, mutect2, varscan2
- USF1 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 838/983 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57040921; called by muse, mutect2, varscan2
- VWA5B1 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 322/1122 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.291); catalogued as rs1431603624; called by muse, mutect2, varscan2
- WNK1 | c.5407A>G p.T1803A (on ENST00000315939 / NM_018979.4; = p.T1556A on NM_014823.3) | Missense Mutation (SNP) | VAF 33/866 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs752331592; called by muse, mutect2
- WNK2 | c.4694C>T p.P1565L (on ENST00000297954 / NM_001282394.1; = p.P1528L on NM_006648.3) | Missense Mutation (SNP) | VAF 501/1558 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1294984088; called by muse, mutect2, varscan2
- ZFHX4 | c.8032C>T p.P2678S | Missense Mutation (SNP) | VAF 462/1197 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50521688; called by muse, mutect2, varscan2
- ZNF729 | c.2314G>A p.E772K | Missense Mutation (SNP) | VAF 270/785 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as rs760465518; called by muse, mutect2, varscan2
- ZNF98 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 234/664 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV100757583; called by muse, varscan2
- ZNF99 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 341/1044 reads (33%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.996); catalogued as COSV68056862; called by muse, mutect2, varscan2
- A1CF | c.1103T>G p.L368R | Missense Mutation (SNP) | VAF 324/832 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- AADACL3 | c.737G>A p.W246* | Nonsense Mutation (SNP) | VAF 698/1229 reads (57%) | called by muse, mutect2, varscan2
- ABCA13 | c.14251G>A p.G4751R | Missense Mutation (SNP) | VAF 356/678 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ABTB1 | c.1243G>A p.E415K (on ENST00000232744 / NM_172027.3; = p.E273K on NM_032548.3) | Missense Mutation (SNP) | VAF 696/1311 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ADAM30 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 646/1291 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- AGTPBP1 | c.2383C>T p.P795S (on ENST00000357081 / NM_001330701.2; = p.P755S on NM_015239.2) | Missense Mutation (SNP) | VAF 230/724 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AKT3 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 237/376 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANHX | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 644/1214 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, varscan2
- ATP10A | c.3257C>T p.A1086V | Missense Mutation (SNP) | VAF 373/546 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ATP8B3 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 216/661 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ATXN7L1 | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 994/1715 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- CAPRIN2 | c.1913T>C p.V638A | Missense Mutation (SNP) | VAF 132/502 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CARNMT1 | c.1179G>A p.M393I | Missense Mutation (SNP) | VAF 175/590 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- CCDC88C | c.297G>A p.M99I | Missense Mutation (SNP) | VAF 698/910 reads (77%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.579); called by muse, varscan2
- CDC45 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 619/1132 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELA3A | c.535C>G p.R179G | Missense Mutation (SNP) | VAF 609/1129 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, varscan2
- CFAP44 | c.1319T>G p.L440W | Missense Mutation (SNP) | VAF 263/467 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- CFAP61 | c.2141G>A p.R714K | Missense Mutation (SNP) | VAF 492/1098 reads (45%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- COL1A1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 261/1349 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- COL20A1 | c.2875C>A p.P959T | Missense Mutation (SNP) | VAF 490/1112 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.062); called by muse, varscan2
- COL24A1 | c.1666C>T p.L556F | Missense Mutation (SNP) | VAF 714/1388 reads (51%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- COL4A4 | c.3034T>A p.F1012I | Missense Mutation (SNP) | VAF 927/1151 reads (81%) | SIFT tolerated (0.38); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CPOX | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 503/1866 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CR1 | c.3520G>A p.G1174R | Missense Mutation (SNP) | VAF 463/813 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRACR2A | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 210/855 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRISP3 | c.343C>A p.H115N (on ENST00000371159 / NM_001368123.1; = p.H97N on NM_006061.4) | Missense Mutation (SNP) | VAF 242/920 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- CTNND2 | c.3529C>A p.H1177N | Missense Mutation (SNP) | VAF 102/1116 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.885); called by muse, mutect2
- CUX2 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 896/1572 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CYP7B1 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 282/724 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DLG2 | c.265C>T p.P89S (on ENST00000650630 / NM_001351274.2; = p.P52S on NM_001142699.3) | Missense Mutation (SNP) | VAF 266/448 reads (59%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- EBF1 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 463/635 reads (73%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- EHMT1 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 288/968 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- ENPEP | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 723/982 reads (74%) | SIFT tolerated (0.32); PolyPhen benign (0.024); called by muse, varscan2
- FDCSP | c.59T>G p.V20G | Missense Mutation (SNP) | VAF 276/396 reads (70%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FDCSP | c.60C>G p.V20= | Splice Region (SNP) | VAF 276/397 reads (70%) | called by muse, mutect2, varscan2
- GALNT15 | c.228_230dup p.E77dup | In Frame Ins (INS) | VAF 444/949 reads (47%) | called by mutect2, varscan2
- GDNF | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 86/1100 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); called by muse, mutect2
- GJB5 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 94/1599 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); called by muse, mutect2
- GMIP | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 478/1243 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- GPR155 | c.2193_2195del p.N732del | In Frame Del (DEL) | VAF 189/562 reads (34%) | called by mutect2, pindel, varscan2
- GRM5 | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 182/282 reads (65%) | SIFT tolerated (0.43); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- HDAC7 | c.944C>T p.S315L (on ENST00000427332; = p.S354L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 365/1079 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- HIVEP3 | c.4322C>T p.T1441I | Missense Mutation (SNP) | VAF 742/1376 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- HNRNPR | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 855/1616 reads (53%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- JPH1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 435/1188 reads (37%) | called by muse, mutect2, varscan2
- KAZN | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 312/1105 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2
- KDM1A | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 516/980 reads (53%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL34 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 624/798 reads (78%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- LAMC3 | c.2773C>T p.Q925* | Nonsense Mutation (SNP) | VAF 355/748 reads (47%) | called by muse, mutect2, varscan2
- LRRC53 | c.1954A>C p.M652L | Missense Mutation (SNP) | VAF 525/1003 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MARCHF7 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 750/955 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MGAT5 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 631/782 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MMAA | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 659/886 reads (74%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- MUC17 | c.8786C>T p.P2929L | Missense Mutation (SNP) | VAF 757/1271 reads (60%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.908); called by muse, varscan2
- MUC5B | c.1919A>T p.N640I | Missense Mutation (SNP) | VAF 66/936 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- MYO18B | c.6172G>A p.E2058K | Missense Mutation (SNP) | VAF 548/1208 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, varscan2
- MYOCD | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 767/999 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- NAALADL2 | c.2134C>T p.L712F | Missense Mutation (SNP) | VAF 310/1192 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- NHLRC1 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 820/1543 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP1 | c.3146C>T p.P1049L | Missense Mutation (SNP) | VAF 446/612 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, varscan2
- ONECUT1 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 594/922 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ONECUT1 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 594/927 reads (64%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR6K3 | c.211C>T p.L71F (on ENST00000368146; = p.L55F on NM_001005327.2) | Missense Mutation (SNP) | VAF 1210/1442 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.32); called by muse, varscan2
- PCNP | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 537/1009 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- PDE1B | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 287/718 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PDK3 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 348/472 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- PKHD1 | c.10072G>A p.D3358N | Missense Mutation (SNP) | VAF 361/1328 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PLEKHG1 | c.2018_2028del p.V673Gfs*4 | Frame Shift Del (DEL) | VAF 134/497 reads (27%) | called by mutect2, pindel, varscan2
- POLB | c.552T>G p.G184= | Splice Region (SNP) | VAF 269/726 reads (37%) | called by muse, varscan2
- PPFIA2 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 215/596 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PROX1 | c.619A>T p.N207Y | Missense Mutation (SNP) | VAF 465/716 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PUS10 | c.761A>C p.N254T | Missense Mutation (SNP) | VAF 498/600 reads (83%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RAD54L | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 276/1047 reads (26%) | called by muse, varscan2
- RASSF3 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 299/827 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, varscan2
- RP1 | c.3935G>A p.G1312E | Missense Mutation (SNP) | VAF 322/960 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SBSN | c.1378C>T p.Q460* | Nonsense Mutation (SNP) | VAF 515/1321 reads (39%) | called by muse, mutect2, varscan2
- SLF1 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 205/296 reads (69%) | SIFT deleterious (0); PolyPhen benign (0.354); called by mutect2, varscan2
- SP8 | c.551C>T p.P184L (on ENST00000361443 / NM_198956.4; = p.P202L on NM_182700.6) | Missense Mutation (SNP) | VAF 858/1576 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, varscan2
- SPAG17 | c.5437G>A p.E1813K | Missense Mutation (SNP) | VAF 268/961 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPATA21 | c.93A>T p.G31= | Splice Region (SNP) | VAF 374/1253 reads (30%) | called by muse, mutect2, varscan2
- SSTR2 | c.458G>A p.W153* | Nonsense Mutation (SNP) | VAF 1146/1370 reads (84%) | called by muse, mutect2, varscan2
- STIL | c.3424C>T p.P1142S | Missense Mutation (SNP) | VAF 458/1418 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TBC1D8B | c.298A>C p.K100Q | Missense Mutation (SNP) | VAF 232/302 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.264); called by muse, varscan2
- TENM2 | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 712/954 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TENM2 | c.2323A>C p.I775L (on ENST00000518659 / NM_001122679.2; = p.I543L on NM_001080428.3) | Missense Mutation (SNP) | VAF 456/1246 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLR8 | c.2523G>A p.M841I (on ENST00000218032 / NM_138636.5; = p.M859I on NM_016610.4) | Missense Mutation (SNP) | VAF 548/687 reads (80%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TMEM30B | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 826/1058 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.117); called by muse, varscan2
- TREM1 | c.610T>C p.F204L | Missense Mutation (SNP) | VAF 493/955 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, varscan2
- TTC39A | c.137A>T p.Y46F | Missense Mutation (SNP) | VAF 235/970 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TTN | c.81838G>A p.G27280R (on ENST00000591111; = p.G19856R on NM_003319.4) | Missense Mutation (SNP) | VAF 495/662 reads (75%) | PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TTN | c.24160G>A p.E8054K (on ENST00000591111; = p.E7127K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 615/769 reads (80%) | PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- TTN | c.22421T>G p.F7474C (on ENST00000591111; = p.F6547C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 667/883 reads (76%) | PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- TYW1B | c.41T>C p.L14S | Missense Mutation (SNP) | VAF 511/1025 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- UHRF2 | c.2308G>T p.A770S | Missense Mutation (SNP) | VAF 292/558 reads (52%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- USP32 | c.4135T>C p.S1379P | Missense Mutation (SNP) | VAF 569/770 reads (74%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- WDR88 | c.807T>A p.T269= | Splice Region (SNP) | VAF 193/487 reads (40%) | called by muse, varscan2
- YEATS2 | c.4061C>T p.S1354F | Missense Mutation (SNP) | VAF 730/1336 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ZDBF2 | c.3749T>C p.L1250P | Missense Mutation (SNP) | VAF 938/1189 reads (79%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF208 | c.2522C>T p.A841V | Missense Mutation (SNP) | VAF 412/1151 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ZNF226 | c.1384C>T p.L462F | Missense Mutation (SNP) | VAF 428/1096 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF449 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 635/779 reads (82%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZSWIM2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 881/1167 reads (75%) | SIFT tolerated (0.64); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ABCA8 | c.1248G>A p.A416= | Silent (SNP) | VAF 661/809 reads (82%) | catalogued as rs767524085, COSV52200256; called by muse, mutect2, varscan2
- ACAD10 | c.1074C>T p.T358= | Silent (SNP) | VAF 470/935 reads (50%) | called by muse, mutect2, varscan2
- AKR1B1 | c.369C>T p.F123= | Silent (SNP) | VAF 294/1259 reads (23%) | catalogued as COSV53646451; called by muse, varscan2
- AL353572.3 | c.15G>A p.T5= | Silent (SNP) | VAF 218/655 reads (33%) | catalogued as rs1330576482; called by muse, varscan2
- ALLC | c.1056C>T p.I352= | Silent (SNP) | VAF 752/978 reads (77%) | catalogued as rs760626316; called by muse, mutect2, varscan2
- ARHGAP32 | c.6252C>T p.I2084= (on ENST00000310343 / NM_001378025.1; = p.I1735= on NM_014715.4) | Silent (SNP) | VAF 238/389 reads (61%) | called by muse, mutect2, varscan2
- ARID3A | c.873G>A p.K291= | Silent (SNP) | VAF 414/1121 reads (37%) | called by muse, mutect2, varscan2
- ARMC2 | c.2259C>T p.I753= | Silent (SNP) | VAF 308/488 reads (63%) | called by muse, mutect2, varscan2
- ATP7B | c.4146G>A p.E1382= | Silent (SNP) | VAF 512/665 reads (77%) | called by muse, varscan2
- ATP8B3 | c.921G>A p.E307= | Silent (SNP) | VAF 209/653 reads (32%) | called by muse, mutect2, varscan2
- C1GALT1C1 | c.648G>A p.K216= | Silent (SNP) | VAF 402/549 reads (73%) | catalogued as COSV58974910; called by muse, mutect2, varscan2
- CAMKV | c.423C>T p.I141= | Silent (SNP) | VAF 524/691 reads (76%) | catalogued as rs748592570, COSV56555938; called by muse, mutect2, varscan2
- CDCP2 | c.747G>A p.K249= | Silent (SNP) | VAF 245/848 reads (29%) | called by muse, varscan2
- CEP162 | c.3312C>T p.L1104= | Silent (SNP) | VAF 1156/1441 reads (80%) | catalogued as rs374562747; called by muse, mutect2, varscan2
- CGNL1 | c.3468G>A p.A1156= | Silent (SNP) | VAF 450/689 reads (65%) | catalogued as rs550324322; called by muse, mutect2, varscan2
- CNBD2 | c.750G>A p.E250= | Silent (SNP) | VAF 970/1188 reads (82%) | called by muse, mutect2, varscan2
- CSMD1 | c.3051C>T p.F1017= (on ENST00000520002; = p.F1016= on NM_033225.6) | Silent (SNP) | VAF 442/693 reads (64%) | catalogued as COSV59340971; called by muse, mutect2, varscan2
- CYP17A1 | c.1443G>A p.K481= | Silent (SNP) | VAF 521/792 reads (66%) | called by muse, varscan2
- CYP4X1 | c.402C>T p.F134= | Silent (SNP) | VAF 283/1031 reads (27%) | called by muse, mutect2, varscan2
- DNAH5 | c.6342C>T p.I2114= | Silent (SNP) | VAF 576/781 reads (74%) | catalogued as COSV54229925; called by muse, mutect2, varscan2
- DNAH8 | c.1017G>A p.R339= | Silent (SNP) | VAF 213/928 reads (23%) | catalogued as rs267601010; called by muse, mutect2, varscan2
- EFCAB6 | c.2205C>T p.F735= | Silent (SNP) | VAF 726/1488 reads (49%) | catalogued as rs780658904; called by muse, mutect2, varscan2
- ENTPD2 | c.699C>T p.Y233= | Silent (SNP) | VAF 633/1414 reads (45%) | called by muse, mutect2, varscan2
- EPHA2 | c.1590G>A p.E530= | Silent (SNP) | VAF 321/1149 reads (28%) | called by muse, mutect2, varscan2
- ERICH3 | c.3798C>T p.V1266= | Silent (SNP) | VAF 869/1664 reads (52%) | catalogued as COSV58598599; called by muse, mutect2, varscan2
- EXOC3L2 | c.582C>A p.I194= | Silent (SNP) | VAF 330/902 reads (37%) | called by muse, mutect2, varscan2
- F13B | c.240C>T p.G80= | Silent (SNP) | VAF 303/488 reads (62%) | catalogued as COSV66375161; called by muse, mutect2, varscan2
- FAM47C | c.2364G>A p.L788= | Silent (SNP) | VAF 523/686 reads (76%) | called by muse, mutect2, varscan2
- FAM71E2 | c.2685G>A p.E895= | Silent (SNP) | VAF 362/1001 reads (36%) | called by muse, mutect2, varscan2
- FMN2 | c.1827C>T p.H609= | Silent (SNP) | VAF 154/583 reads (26%) | catalogued as rs973160262; called by muse, mutect2, varscan2
- FMNL1 | c.3222G>A p.T1074= | Silent (SNP) | VAF 776/1015 reads (76%) | called by muse, mutect2, varscan2
- GABBR2 | c.2220C>T p.F740= | Silent (SNP) | VAF 202/698 reads (29%) | catalogued as rs754518079, COSV99411322; called by muse, mutect2, varscan2
- GAL3ST4 | c.1329G>A p.L443= | Silent (SNP) | VAF 789/1329 reads (59%) | catalogued as rs761817361; called by muse, varscan2
- GNA14 | c.216G>A p.T72= | Silent (SNP) | VAF 307/1052 reads (29%) | catalogued as rs755246583, COSV59019089; called by muse, mutect2, varscan2
- GPCPD1 | c.207C>T p.F69= | Silent (SNP) | VAF 162/843 reads (19%) | called by muse, mutect2, varscan2
- HTR1E | c.405G>A p.T135= | Silent (SNP) | VAF 454/738 reads (62%) | catalogued as rs371516749, COSV59509271; called by muse, varscan2
- IGSF10 | c.3885C>T p.N1295= | Silent (SNP) | VAF 916/1657 reads (55%) | called by muse, mutect2, varscan2
- INTS7 | c.1299C>T p.T433= | Silent (SNP) | VAF 408/642 reads (64%) | called by muse, mutect2, varscan2
- JPH1 | c.1197C>T p.R399= | Silent (SNP) | VAF 435/1181 reads (37%) | called by muse, mutect2, varscan2
- KBTBD3 | c.375C>T p.F125= | Silent (SNP) | VAF 329/535 reads (61%) | catalogued as rs1327239412; called by muse, mutect2, varscan2
- KCNN2 | c.1528C>T p.L510= (on ENST00000264773; = p.L722= on NM_021614.4) | Silent (SNP) | VAF 632/878 reads (72%) | catalogued as rs774239362, COSV53297674; called by muse, varscan2
- KDM2B | c.1371C>T p.L457= | Silent (SNP) | VAF 851/1597 reads (53%) | catalogued as rs368940476; called by muse, mutect2, varscan2
- LIPJ | c.627C>T p.F209= | Silent (SNP) | VAF 487/631 reads (77%) | catalogued as rs751090349, COSV64245154, COSV64245189; called by muse, mutect2, varscan2
- LIPJ | c.1065C>T p.Y355= | Silent (SNP) | VAF 260/360 reads (72%) | catalogued as rs751810861; called by muse, mutect2, varscan2
- LRIT2 | c.501C>T p.S167= | Silent (SNP) | VAF 824/1055 reads (78%) | catalogued as COSV100928324; called by muse, varscan2
- LRP1B | c.6096T>G p.V2032= | Silent (SNP) | VAF 725/909 reads (80%) | called by muse, mutect2, varscan2
- LRRC8C | c.396C>T p.L132= | Silent (SNP) | VAF 369/1358 reads (27%) | called by muse, mutect2, varscan2
- LYPD2 | c.195G>A p.G65= | Silent (SNP) | VAF 234/691 reads (34%) | catalogued as rs778829542; called by muse, mutect2, varscan2
- LYPLA1 | c.447G>T p.R149= | Silent (SNP) | VAF 327/865 reads (38%) | called by muse, mutect2, varscan2
- MDN1 | c.6564C>T p.I2188= | Silent (SNP) | VAF 229/362 reads (63%) | catalogued as rs780193499; called by muse, mutect2, varscan2
- MGAT4C | c.699C>T p.F233= | Silent (SNP) | VAF 329/934 reads (35%) | catalogued as COSV100152786; called by muse, mutect2, varscan2
- MUC16 | c.41937C>T p.I13979= | Silent (SNP) | VAF 302/796 reads (38%) | catalogued as rs552123478; called by muse, varscan2
- MUC16 | c.34356C>T p.V11452= | Silent (SNP) | VAF 328/917 reads (36%) | called by muse, varscan2
- MUC22 | c.3765C>T p.T1255= | Silent (SNP) | VAF 590/2553 reads (23%) | called by muse, varscan2
- MYBPC3 | c.973C>T p.L325= | Silent (SNP) | VAF 670/884 reads (76%) | called by muse, mutect2, varscan2
- NHLRC1 | c.852C>T p.A284= | Silent (SNP) | VAF 819/1548 reads (53%) | called by muse, mutect2, varscan2
- NOS3 | c.2931C>T p.S977= | Silent (SNP) | VAF 279/1438 reads (19%) | called by muse, mutect2, varscan2
- NRF1 | c.321A>G p.Q107= | Silent (SNP) | VAF 579/965 reads (60%) | called by muse, varscan2
- NXN | c.285G>A p.Q95= | Silent (SNP) | VAF 471/617 reads (76%) | called by muse, mutect2, varscan2
- OAS3 | c.756C>T p.L252= | Silent (SNP) | VAF 578/1060 reads (55%) | called by muse, varscan2
- OR13H1 | c.846C>T p.P282= | Silent (SNP) | VAF 500/644 reads (78%) | called by muse, varscan2
- OR14C36 | c.399C>T p.I133= | Silent (SNP) | VAF 409/654 reads (63%) | catalogued as rs150366522, COSV58602888; called by muse, mutect2, varscan2
- OR1L6 | c.147C>T p.F49= (on ENST00000373684; = p.F13= on NM_001004453.2) | Silent (SNP) | VAF 246/832 reads (30%) | catalogued as rs866844323; called by muse, varscan2
- OR8J2 | c.615C>A p.T205= | Silent (SNP) | VAF 507/702 reads (72%) | catalogued as rs1456494469; called by muse, mutect2, varscan2
- PGK2 | c.213C>A p.P71= | Silent (SNP) | VAF 736/1426 reads (52%) | called by muse, varscan2
- PI4KA | c.6228G>A p.K2076= | Silent (SNP) | VAF 633/1265 reads (50%) | called by muse, mutect2, varscan2
- PKD1 | c.8800C>T p.L2934= | Silent (SNP) | VAF 460/637 reads (72%) | catalogued as rs1160562832; called by muse, mutect2, varscan2
- PPHLN1 | c.855T>C p.S285= | Silent (SNP) | VAF 304/906 reads (34%) | called by muse, mutect2, varscan2
- PRAMEF5 | c.390G>A p.R130= | Silent (SNP) | VAF 180/1628 reads (11%) | called by muse, varscan2
- PRPF40B | c.903C>T p.A301= (on ENST00000380281; = p.A295= on NM_012272.3) | Silent (SNP) | VAF 285/887 reads (32%) | called by muse, mutect2, varscan2
- PTPRE | c.654C>T p.F218= | Silent (SNP) | VAF 492/680 reads (72%) | catalogued as rs1190538123; called by muse, varscan2
- RAD54L | c.702C>T p.L234= | Silent (SNP) | VAF 772/1347 reads (57%) | catalogued as rs1208771331, COSV64336310; called by muse, mutect2, varscan2
- RAI1 | c.1683T>G p.P561= | Silent (SNP) | VAF 439/1062 reads (41%) | called by muse, mutect2, varscan2
- RBBP6 | c.285G>A p.A95= | Silent (SNP) | VAF 405/577 reads (70%) | catalogued as rs148048189; called by muse, mutect2, varscan2
- RBM17 | c.303C>T p.D101= | Silent (SNP) | VAF 556/797 reads (70%) | catalogued as rs779802362; called by muse, mutect2, varscan2
- RIMBP3C | c.4873C>T p.L1625= | Silent (SNP) | VAF 16/72 reads (22%) | called by mutect2, varscan2
- RPS19 | c.123G>A p.K41= | Silent (SNP) | VAF 342/901 reads (38%) | called by muse, mutect2, varscan2
- RSPO1 | c.582G>A p.K194= | Silent (SNP) | VAF 726/1438 reads (50%) | called by muse, varscan2
- SAFB2 | c.2583C>A p.A861= | Silent (SNP) | VAF 528/1257 reads (42%) | called by muse, mutect2, varscan2
- SCML1 | c.780G>A p.V260= (on ENST00000380041 / NM_001037540.3; = p.V233= on NM_006746.6) | Silent (SNP) | VAF 537/676 reads (79%) | called by muse, mutect2, varscan2
- SEC16B | c.1521G>A p.S507= | Silent (SNP) | VAF 901/1118 reads (81%) | catalogued as rs778408889; called by muse, mutect2, varscan2
- SEL1L2 | c.1956G>A p.T652= | Silent (SNP) | VAF 182/854 reads (21%) | catalogued as rs192814784; called by muse, mutect2, varscan2
- SH3BP4 | c.2049C>T p.I683= | Silent (SNP) | VAF 912/1156 reads (79%) | catalogued as rs750018242; called by muse, varscan2
- SIGLEC11 | c.1509C>T p.F503= | Silent (SNP) | VAF 511/1408 reads (36%) | catalogued as rs377108269; called by muse, mutect2, varscan2
- SLC6A11 | c.177C>T p.F59= | Silent (SNP) | VAF 672/938 reads (72%) | called by muse, varscan2
- SLC9A4 | c.345C>T p.F115= | Silent (SNP) | VAF 460/1278 reads (36%) | catalogued as rs1414664004, COSV99763526; called by muse, varscan2
- SMG9 | c.1365C>T p.S455= | Silent (SNP) | VAF 361/900 reads (40%) | catalogued as rs866912272; called by muse, mutect2, varscan2
- SNRPA | c.570T>A p.L190= | Silent (SNP) | VAF 422/1186 reads (36%) | called by muse, mutect2, varscan2
- TCEAL5 | c.279G>A p.Q93= | Silent (SNP) | VAF 585/767 reads (76%) | catalogued as rs1256095981; called by muse, mutect2, varscan2
- TLL1 | c.2964T>C p.D988= | Silent (SNP) | VAF 484/695 reads (70%) | catalogued as rs578172463; called by muse, mutect2, varscan2
- TMEM184B | c.796C>T p.L266= | Silent (SNP) | VAF 541/1451 reads (37%) | catalogued as rs1205799861; called by muse, mutect2, varscan2
- TNFSF9 | c.732C>T p.I244= | Silent (SNP) | VAF 370/951 reads (39%) | catalogued as COSV55538198; called by muse, mutect2, varscan2
- TTC39A | c.138C>T p.Y46= | Silent (SNP) | VAF 236/964 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.22422C>T p.F7474= (on ENST00000591111; = p.F6547= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 659/873 reads (75%) | catalogued as COSV59964382; called by muse, mutect2, varscan2
- UBXN11 | c.1188C>T p.L396= (on ENST00000374221 / NM_183008.2; = p.L363= on NM_145345.2) | Silent (SNP) | VAF 387/1368 reads (28%) | called by muse, mutect2, varscan2
- UGT2B4 | c.303A>T p.P101= | Silent (SNP) | VAF 575/731 reads (79%) | called by muse, mutect2, varscan2
- UNC13C | c.1626C>T p.F542= | Silent (SNP) | VAF 389/604 reads (64%) | catalogued as COSV52912814, COSV99524343; called by muse, varscan2
- URB2 | c.4017C>T p.N1339= | Silent (SNP) | VAF 455/727 reads (63%) | catalogued as rs757887593; called by muse, mutect2, varscan2
- USP17L10 | c.825C>T p.V275= | Silent (SNP) | VAF 746/1198 reads (62%) | catalogued as rs373485739; called by muse, mutect2, varscan2
- VPS13D | c.6927C>T p.S2309= | Silent (SNP) | VAF 177/750 reads (24%) | called by muse, mutect2, varscan2
- ZAN | c.4950G>A p.T1650= | Silent (SNP) | VAF 859/1412 reads (61%) | catalogued as rs1335393587, COSV61805366; called by muse, mutect2, varscan2
- ZNF628 | c.3081C>T p.V1027= | Silent (SNP) | VAF 476/1171 reads (41%) | called by muse, mutect2, varscan2
- CCDC150 | c.1866+689T>G | Intron (SNP) | VAF 794/1052 reads (75%) | called by muse, mutect2, varscan2
- FAM98B | chr15:38484553 del A | 3'Flank (DEL) | VAF 246/546 reads (45%) | called by pindel, varscan2
- HDAC8 | chrX:72572900 G>A | 5'Flank (SNP) | VAF 374/492 reads (76%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-1829G>A | Intron (SNP) | VAF 368/546 reads (67%) | called by muse, mutect2, varscan2
- MBD4 | c.1665+9C>T | Intron (SNP) | VAF 378/1452 reads (26%) | called by muse, mutect2, varscan2
- NPAP1L | n.842C>T | RNA (SNP) | VAF 245/372 reads (66%) | called by muse, varscan2
- PPP1R9A | c.2758-2146_2758-2144dup | Intron (INS) | VAF 399/1335 reads (30%) | called by mutect2, pindel, varscan2
- PRR29 | c.*87C>T | 3'UTR (SNP) | VAF 1135/1392 reads (82%) | called by muse, varscan2
- STYK1 | c.*140G>A | 3'UTR (SNP) | VAF 228/552 reads (41%) | called by muse, mutect2, varscan2
- TBC1D1 | c.1911-1070G>A | Intron (SNP) | VAF 364/487 reads (75%) | catalogued as rs879251866; called by muse, mutect2, varscan2
- Z99774.2 | chr22:26672682 G>T | 3'Flank (SNP) | VAF 119/1762 reads (7%) | called by muse, mutect2
- ZNF414 | chr19:8510872 G>A | 3'Flank (SNP) | VAF 287/489 reads (59%) | called by muse, varscan2
